Surgical pathology report (de-identified scan), TCGA case TCGA-29-2435, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2435-01A (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling NOS

Per surgeon: history of adenocarcinoma on cervix biopsy. Unknown origin. Left ovarian mass.

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)". Received unfixed for frozen section and placed in formalin is a 183 gram, 6.5 x 4.5 x 3.5 cm previously disrupted ovary with attached 7 x 1.5 x 1.5 cm adherent fallopian tube (no fimbria present). Upon sectioning, the ovary has been completely replaced by a 6.5 x 4 x 4.1 cm firm, homogenous yellow-white mass with focal necrosis that focally extends through the adherent fallopian tube. A section of the mass at the capsule was previously frozen as AF1. Normal ovarian parenchyma is absent.

The fallopian tube mucosa is absent and the dilated lumen (up to 2 cm) is filled with a yellow-green mucoid material and adherent gray papillary excrescences.

BLOCK SUMMARY:

- A1- frozen section control for AF1.
- A2-A4- mass with respect to fallopian tube invasion.
- A5- fallopian tube with excrescences.
- A6- mass with respect to ovarian capsule.
- A7- mass with to adjacent vasculature.

B. "Uterus, cervix, right tube and ovary". Received unfixed and placed in formalin at m. on is a 73 gram, 8.2 x 5.5 x 3 cm uterus with attached right adnexa (ovary: 2.4 x 1.2 x 1.1 cm, fallopian tube: 2.5 cm long x 0.7 cm in average diameter). The paracervical soft tissue is inked blue.

The 3.5 x 3.2 cm endometrial cavity is lined with a 0.1 cm thick endometrium with scattered hemorrhage that contains a 0.5 x 0.4 x 0.1 cm hemorrhagic endometrial polyp in the anterior fundus that does not grossly invade the endometrium. The 1.8 cm myometrium has diffuse congested vasculature and a 0.3 cm in diameter simple cyst underlying the anterior endometrium. The posterior myometrium has a 1.6 cm in diameter white, well circumscribed nodule without hemorrhage or necrosis.

The 3.1 cm long endocervical canal is lined by a unremarkable mucosa and leads out to a smooth, white-tan and unremarkable ectocervix. The uterine serosa is pink-tan and unremarkable. The attached ovary and fimbriated fallopian tube are grossly unremarkable.

BLOCK SUMMARY:

- B1- anterior cervix.
- B2- anterior endomyometrium, full thickness with cyst.
- B3- anterior endomyometrium, full thickness with hemorrhagic polyp, entirely.
- B4- posterior cervix.
- B5- posterior endomyometrium with nodule.
- B6- representative ovary and fallopian tube.

C. "Left pelvic lymph node". Received unfixed and placed in formalin at is a 3.8 x 2.2 x 0.7 cm aggregate of adipose tissue that is palpated for lymph node candidates and one lymph node candidate, 1.6 cm in greatest dimension is identified.

BLOCK SUMMARY:

[page 2 of 3]
- C1- one lymph node candidate, bisected.
- C2- remainder of specimen in a mesh bag.

D. "Omentum". Received unfixed and placed in formalin at is a 9 x 9 x 4 cm portion of omentum. No mass lesions are identified. Representative sections are submitted in blocks D1-D2.

INTRA OPERATIVE CONSULTATION:

- A. "Left tube and ovary": AF1- representative tumor- high grade carcinoma, favor serous papillary grade III.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the Immunopathology Laboratory, the U.S. Food and Drug Administration. Some of them may not be cleared or approved by clearance or approval is not necessary. The FDA has determined that such purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

PATHOLOGIC STAGE:

PROCEDURE: Hysterosalpingo-oophorectomy and node biopsy

PATHOLOGIC STAGE (AJCC 6th Edition): pT2a pN0 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

- A. "LEFT TUBE AND OVARY (AF1)": CARCINOMA

OVARY:

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 6.5 X 4.1 X 4 CM.

WEIGHT: 183 GRAMS

SEROSA: POSITIVE FOR TUMOR

FALLOPIAN TUBE: POSITIVE FOR TUMOR

- B. "UTERUS, CERVIX, RIGHT TUBE AND OVARY":

UTERUS, 73 GRAMS

ENDOMETRIUM: ENDOMETRIAL POLYP AND ATROPHIC ENDOMETRIUM

MYOMETRIUM: LEIOMYOMATA

CERVIX: NEGATIVE FOR TUMOR.

SEROSA: NEGATIVE FOR TUMOR.

RIGHT FALLOPIAN TUBE: NEGATIVE FOR CARCINOMA.

[page 3 of 3]
RIGHT OVARY: NEGATIVE FOR CARCINOMA.

C. "LEFT PELVIC LYMPH NODE":

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

D. "OMENTUM" (PARTIAL OMENTECTOMY):

ADIPOSE TISSUE WITH CHRONIC INFLAMMATION, NEGATIVE FOR CARCINOMA.

COMMENT: In part A, immunoperoxidase stains of the tumor are positive for WT1, Berp4, and CK7 and are negative for CK20, TTF1, CDX2, and calretinin. This pattern of staining is not entirely specific, but is very consistent with an ovarian primary carcinoma.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3262342f-03c8-4ca0-834a-bf9aa6c392d7 (TCGA-29-2435.6EF128AE-31B6-483A-B0DD-9626CEEC278E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).